TCGA case TCGA-A6-2674 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/57cdaa1c-4e94-4a28-ab3b-300c0457555f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (3)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 72.0 years (26,292 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,331 days (3.6 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 7; Lymph nodes tested: 20; Lymphatic invasion present: No; Non nodal tumor deposits: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 75 days; Days to treatment end: 237 days; Number of cycles: 12; Treatment dose: 9,150 mg; Prescribed dose: 800; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 75 days; Days to treatment end: 239 days; Number of cycles: 12; Treatment dose: 54,600 mg; Prescribed dose: 4800; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 75 days; Days to treatment end: 237 days; Number of cycles: 12; Treatment dose: 9,150 mg; Prescribed dose: 800; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 75 days; Days to treatment end: 237 days; Number of cycles: 12; Treatment dose: 1,950 mg; Prescribed dose: 170; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 90 days; Days to treatment end: 237 days; Number of cycles: 10; Treatment dose: 4,400 mg; Prescribed dose: 440; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 761 days (2.1 years); Days to treatment end: 944 days (2.6 years); Number of cycles: 12; Treatment dose: 5,173 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Initial disease status: Recurrent Disease; Days to treatment start: 761 days (2.1 years); Days to treatment end: 946 days (2.6 years); Number of cycles: 12; Treatment dose: 59,112 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Initial disease status: Recurrent Disease; Days to treatment start: 761 days (2.1 years); Days to treatment end: 944 days (2.6 years); Number of cycles: 12; Treatment dose: 9,852 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Initial disease status: Recurrent Disease; Days to treatment start: 761 days (2.1 years); Days to treatment end: 944 days (2.6 years); Number of cycles: 12; Treatment dose: 1,750 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Initial disease status: Recurrent Disease; Days to treatment start: 761 days (2.1 years); Days to treatment end: 944 days (2.6 years); Number of cycles: 12; Treatment dose: 2,093 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 74.0 years (27,027 days); Days to diagnosis: 735 days (2.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 75.3 years (27,511 days); Days to diagnosis: 1,219 days (3.3 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS.

Follow-up (5 entries)
- Days to follow up: 523 days (1.4 years); Disease response: Tumor Free.
- Day 735 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 735 days (2.0 years).
- Days to follow up: 761 days (2.1 years); Disease response: With Tumor.
- Day 1,219 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,219 days (3.3 years).
- Days to follow up: 1,331 days (3.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 32.8 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85.6 kg; Height: 175.2 cm; BMI: 27.9.

Family history
- Relative with cancer history: no.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-2674-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-A6-2674-01A-02-BS2: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
  Slide TCGA-A6-2674-01A-01-BS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-A6-2674-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide TCGA-A6-2674-01B-04-BS4: Section location: Bottom; Percent tumor cells: 73; Percent tumor nuclei: 68; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 25; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 15.
  Slide TCGA-A6-2674-01B-03-BS3: Section location: Top; Percent tumor cells: 68; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 30; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 20.
- Sample TCGA-A6-2674-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-2674-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-A6-2674-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 0.7; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; CEA level pretreatment: 32.8; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Avastin.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Levcovorin.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: 5 FU.
- Drug treatment 6: Regimen number: 2; Therapy regimen: Recurrence.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form 3, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,331 days; disease-specific survival: no event (censored), 1,331 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 735 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A6-2674-01A-02D-1549-01): tumor purity 0.25, ploidy 3.14, whole-genome doublings 1.
